Gene-level copy-number profile of tumor specimen C3L-08244-03 from CPTAC case C3L-08244, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G1; Age at diagnosis: 71.1 years (25,964 days).
Specimen C3L-08244-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0ecf8d59-e359-4b57-94bd-b76a5ea890b8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08244-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,866 have no estimate.
https://portal.gdc.cancer.gov/files/10d99c4b-225d-4735-bfca-35f46ef9ed5b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 356; copy number 1: 947; copy number 2: 22,233; copy number 3: 19,288; copy number 4: 11,263; copy number 5: 3,812; copy number 6: 471; copy number 7: 171; copy number 8: 36; copy number 9: 62; copy number 10: 72; copy number 11: 7; copy number 12: 8; copy number 14: 3; copy number 24: 11; copy number 44: 2; copy number 483: 15.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:67,701,886–67,734,451, 3 genes (within-gene range 0–2): RDH12, RN7SL369P, RPL21P9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,670 genes in 57 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:5,478,736–12,667,086, 204 genes, copy number 5–8 (broad region; genes not listed).
- chr1:15,247,272–15,472,091, 7 genes, copy number 5 (within-gene range 4–5): FHAD1, FHAD1-AS1, AL031283.2, AL031283.1, EFHD2, CTRC, CELA2A.
- chr1:15,988,182–16,437,424, 22 genes, copy number 5: AL355994.1, AL355994.5, TBC1D3P6, SRARP, AL355994.3, HSPB7, CLCNKA, AL355994.2, CLCNKB, FAM131C, EPHA2, AL451042.2, AL451042.1, ARHGEF19-AS1, ARHGEF19, ANO7L1, CPLANE2, MT1XP1, FBXO42, SZRD1, RPL22P3, SPATA21.
- chr1:22,835,713–23,177,808, 10 genes, copy number 5 (within-gene range 4–5): AL512444.1, MIR4253, LACTBL1, TEX46, KDM1A, AL031428.1, MIR3115, AL031428.2, LUZP1, AL161672.1.
- chr1:24,968,423–25,906,991, 34 genes, copy number 5: AL445471.1, MIR4425, LINC02793, AL050344.1, IFITM3P7, AL031432.1, SYF2, RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1, TMEM50A, RHCE, AL031284.1, MACO1, LDLRAP1, AL606491.1, MAN1C1, AL031280.1, SELENON, AL020996.2, AL020996.1, MTFR1L, AL020996.3, AUNIP, AL033528.2, PAQR7, Y_RNA, STMN1, SNRPFP2, AL033528.1, MIR3917.
- chr1:26,234,200–26,575,030, 16 genes, copy number 5: CEP85, AL355877.1, SH3BGRL3, UBXN11, CD52, CRYBG2, AL451139.1, ZNF683, LIN28A, DHDDS, AL513365.1, DHDDS-AS1, HMGN2, DPPA2P2, RPS6KA1, MIR1976.
- chr1:28,668,778–28,881,835, 6 genes, copy number 5: GMEB1, AL645729.1, YTHDF2, OPRD1, AL009181.1, Y_RNA.
- chr1:38,885,807–41,484,683, 88 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:151,364,304–151,853,712, 33 genes, copy number 5: SELENBP1, PSMB4, POGZ, RNY4P25, CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1, SNX27, AL391335.1, RNU6-1062P, CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5.
- chr1:154,697,455–155,563,162, 51 genes, copy number 5 (within-gene range 4–5): KCNN3, PMVK, AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1, ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4.
- chr1:201,829,149–202,592,706, 28 genes, copy number 5 (within-gene range 4–5): IPO9, MIR6739, SHISA4, AL513217.1, LMOD1, TIMM17A, SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3, GPR37L1, ARL8A, PTPN7, PTPRVP, LGR6, UBE2T, PPP1R12B, CYCSP4, RNU6-89P, AC099336.1, AC099336.2.
- chr1:227,123,895–227,520,619, 15 genes, copy number 5: AL353689.3, AL451047.1, AL627308.1, AL627308.2, AL627308.3, LINC01641, NUCKS1P1, AL606462.1, BTF3P9, AL451054.2, AL451054.3, TUBB8P10, TUBB8P9, AL451054.1, AL451054.4.
- chr1:246,509,038–246,839,611, 15 genes, copy number 5 (within-gene range 4–5): AL356583.1, LINC01743, AL356583.3, AL356583.2, TFB2M, CNST, AL591623.1, AL591623.2, AL591848.2, AL591848.1, SCCPDH, RPL35AP6, KIF28P, AL591848.3, LINC01341.
- chr2:172,137,345–172,506,459, 6 genes, copy number 5 (within-gene range 4–5): AC104088.1, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1.
- chr5:987,180–1,445,440, 16 genes, copy number 6–7: AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3.
- chr5:32,103,445–32,888,145, 15 genes, copy number 5 (within-gene range 4–5): AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, NPR3, AC025459.1.
- chr6:905,445–1,324,022, 6 genes, copy number 5–6: AL356130.1, LINC01622, AL033381.2, AL033381.1, FOXQ1, LINC01394.
- chr6:30,466,452–31,158,238, 52 genes, copy number 5: TMPOP1, SUCLA2P1, RANP1, HLA-E, LINC02569, GNL1, PRR3, ABCF1, MIR877, PPP1R10, MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243, LINC02570, RN7SKP186, DDR1-DT, DDR1, MIR4640, GTF2H4, AL669830.1, VARS2, SFTA2, Y_RNA, MUCL3, HCG21, NAPGP2, MUC21, MUC22, HCG22, RNU6-1133P, C6orf15, PSORS1C1, CDSN, PSORS1C2, POLR2LP1, CCHCR1.
- chr6:43,474,186–44,184,401, 28 genes, copy number 5–7: RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, MRPL14, TMEM63B, CAPN11.
- chr6:63,193,072–63,616,361, 15 genes, copy number 5: AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18.
- chr9:33,503,655–35,149,184, 92 genes, copy number 7–10 (broad region; genes not listed).
- chr9:35,406,755–38,068,687, 93 genes, copy number 7–12 (within-gene range 4–12) (broad region; genes not listed).
- chr9:41,890,314–68,644,442, 204 genes, copy number 5–6 (broad region; genes not listed).
- chr9:127,397,138–128,130,628, 40 genes, copy number 5–6: SLC2A8, ZNF79, RPL12, SNORA65, LRSAM1, Y_RNA, NIBAN2, STXBP1, AL162426.1, PTRH1, MIR3911, CFAP157, TTC16, TOR2A, SH2D3C, AL162586.2, CDK9, MIR3960, MIR2861, FPGS, ENG, AL162586.1, Y_RNA, RNA5SP296, AK1, AL157935.2, MIR4672, ST6GALNAC6, ST6GALNAC4, PIP5KL1, AL157935.1, DPM2, FAM102A, AL360268.2, NAIF1, SLC25A25, AL360268.1, SLC25A25-AS1, PTGES2, PTGES2-AS1.
- chr10:80,394–38,783,108, 640 genes, copy number 5–8 (broad region; genes not listed).
- chr10:120,608,580–121,928,492, 15 genes, copy number 483 (within-gene range 3–483): AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1.
- chr11:118,925,164–119,081,972, 20 genes, copy number 5 (within-gene range 3–5): UPK2, RN7SL688P, Y_RNA, FOXR1, Metazoa_SRP, Y_RNA, CENATAC-DT, CENATAC, RPL23AP64, AP003392.1, AP003392.2, RPS25, TRAPPC4, AP003392.15, SLC37A4, AP003392.3, HYOU1, AP003392.4, AP003392.5, VPS11.
- chr13:18,467,172–81,691,072, 943 genes, copy number 5–6 (broad region; genes not listed).
- chr13:83,145,540–114,337,626, 385 genes, copy number 5 (broad region; genes not listed).
- chr16:18,781,295–19,121,629, 14 genes, copy number 5 (within-gene range 4–5): RPS15A, AC138811.2, ARL6IP1, AC138811.1, SMG1, AC092287.1, TMC7, RNU6-1340P, AC099518.4, AC099518.2, COQ7, AC099518.1, AC099518.6, ITPRIPL2.
- chr16:46,469,341–46,978,983, 20 genes, copy number 5: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3.
- chr16:50,368,580–50,681,353, 9 genes, copy number 5 (within-gene range 4–5): AC007493.2, LINC02178, AC007493.1, NKD1, AC007608.2, AC007608.4, AC007608.1, AC007608.3, SNX20.
- chr16:69,933,081–70,173,483, 10 genes, copy number 5 (within-gene range 4–5): MIR140, CLEC18A, AC026468.1, PDXDC2P-NPIPB14P, NPIPB14P, PDXDC2P, MIR1972-2, AC009022.1, PDPR, AC009060.1.
- chr16:70,202,354–70,445,399, 14 genes, copy number 5: AC009060.2, SMG1P7, EXOSC6, AARS1, RN7SL279P, DDX19B, AC012184.2, AC012184.3, DDX19A, AC012184.4, ST3GAL2, AC012184.1, RPS27P26, RNU6-23P.
- chr16:88,177,289–88,856,970, 28 genes, copy number 5 (within-gene range 4–5): AC134312.2, AC134312.5, LINC02182, AC134312.6, AC138512.1, ZNF469, ZFPM1, MIR5189, AC116552.1, ZC3H18, IL17C, CYBA, MVD, SNAI3-AS1, SNAI3, RNF166, AC138028.3, CTU2, AC138028.6, PIEZO1, MIR4722, AC138028.4, AC138028.2, AC138028.5, AC138028.1, CDT1, APRT, GALNS.
- chr18:57,027,832–58,019,061, 19 genes, copy number 5 (within-gene range 4–5): WDR7-OT1, LINC-ROR, AC100775.1, BOD1L2, LINC02565, RNU6-737P, ST8SIA3, AC090340.1, ONECUT2, FECH, AC100847.1, NARS1, AC027097.1, AC027097.2, ATP8B1, RNU6-742P, RSL24D1P11, LINC01897, HMGN1P30.
- chr19:29,698,886–30,713,538, 13 genes, copy number 24–44 (within-gene range 3–44): C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1.
- chr20:87,250–16,053,197, 288 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr20:15,552,157–64,327,972, 1,109 genes, copy number 5–14 (broad region; genes not listed).
- chr21:10,482,738–13,067,033, 9 genes, copy number 6 (within-gene range 3–6): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 932. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
